Surgical pathology report (de-identified scan), TCGA case TCGA-PE-A5DC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Fox Chase, specimen TCGA-PE-A5DC-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: F
Location:
Date Collected:
Date Received:
Physician:
Copy To:
Clinical History/Diagnosis: Right Breast Cancer

Source of Specimen(s):
A: Sentinel Node right axilla
B: right Breast Lumpectomy
C: final inferior Margin
D: right Axillary Contents

Gross Description:
Received in four parts.
Source of Tissue: 1. Labeled #1, "sentinel node right axilla"

Touch Preparation Evaluation: 1TPA-1TPB- METASTATIC CARCINOMA PER

Gross Description: Received fresh for touch preparation evaluation with patient's name and medical record number labeled "sentinel node right axilla" are two gray-tan blue dye stained lymph nodes, 0.8 and 2.0 cm in greatest dimension. They are sectioned, touch preparations are made and representative sections are submitted in two blocks.

Designation of Sections: 1A: 1TPA (representative section), 1B: 1TPB (entire lymph node)

Summary of Sections: multiple

Source of Tissue: 2. Labeled #2, "right breast lumpectomy"

Gross Description: Received fresh with patient name and medical record number labeled "right breast lumpectomy" is a 190 grams, 11.0 x 10.5 x 4.0 cm yellow-tan fragment of breast tissue. There is a short stitch denoting the superior margin and a long stitch denoting the lateral margin. The margins are inked in black, the specimen is serially sectioned to reveal yellow-tan adipose tissue with a moderate amount of dense white-tan connective tissue. There is a 4.0 x 2.5 x 1.8 cm firm mass having tan

CBCE ICD-O-3
Carcinoma, lobular
infiltrating NOS 8520/3
path Carcinoma, pleomorphic
lobular 8520/3
Site @ Breast NOS C50.9
JW 5/24/13

[page 2 of 3]
gritty cut surfaces with irregular borders. This grossly appears to come closest to the inked anterior, posterior and inferior margins. Representative sections are submitted in ten blocks.

Designation of Sections: 2A- superior, 2B-2C- inferior, 2D- medial, 2E- lateral, 2F-2H- anterior, 2I-2J- posterior

Summary of Sections: multiple

Source of Tissue: 3. Labeled #3, "final inferior margin"

Gross Description: Received fresh with patient name and medical record number labeled "final inferior margin" is a 5.0 x 3.5 x 1.6 cm yellow-tan focally blue dye stained fragment of breast tissue. There are two sutures present marking the new margin and this area is inked in black. The specimen is sectioned to reveal yellow-tan adipose tissue with a moderate amount of dense white-tan connective tissue. Representative sections are submitted in four blocks.

Designation of Sections: 3A-3D

Summary of Sections: multiple

Source of Tissue: 4. Labeled #4, "right axillary contents"

Gross Description: Received fresh with patient name and medical record number labeled "right axillary contents" are 15.0 x 12.5 x 2.5 cm of yellow-tan axillary fat. There are multiple palpable lymph nodes, 0.3 to 2.5 cm in greatest dimension. The lymph nodes are entirely submitted in fourteen blocks.

Designation of Sections: 4A- one lymph node, 4B- one lymph node, 4C- one lymph node, 4D- one lymph node, 4E- one lymph node, 4F- one lymph node, 4G-4I- one lymph node, 4J-4N- multiple single lymph nodes

Summary of Sections: multiple

Final Diagnosis:

1. Sentinel lymph node right axilla, excision:
- Metastatic adenocarcinoma in two of two lymph nodes (2/2) with extracapsular extension.
2. Right breast, lumpectomy:
- In situ and invasive pleomorphic lobular carcinoma, grade III (4 cm)

[page 3 of 3]
extending to less than 0.1 mm of the inferior and posterior margins and 0.2 cm from the anterior margin.

- Other margins negative for tumor.
- Previous biopsy site changes.
- Extensive angiolymphatic invasion is present.

3. Right breast, final inferior margin, excision:

- Residual invasive and in situ carcinoma with angiolymphatic invasion.
- New margin negative for tumor.

4. Right axillary contents, regional resection:

- Metastatic adenocarcinoma in three of twenty-nine lymph nodes (3/29) with extracapsular extension.
- Axillary breast tissue is present.

Stage pT2,N2,Mx.

Source: NCI Genomic Data Commons file f29b0118-8d10-4be1-aa5d-9de5a35ff07d (TCGA-PE-A5DC.8693580D-FCB3-4943-9C2F-5F3DABFB5AF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).